Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAQ0, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAQ0-01A (Primary Tumor).

[page 1 of 4]
TSS Patient ID:

Surgical Date:

Gross Description: Pancreas: Received is a Whipple specimen measuring 17 x 8 x 5 cm, consisting of duodenum (15 cm in length x 4.5 cm depth) and pancreas (8 x 5.4 x 2 cm). The proximal and distal margins of the duodenum are received closed. The duodenum is opened to reveal a duodenal mucosa with normal folding pattern, with the more distal portion of the duodenal mucosa appearing darker and congested. Additionally, there is a wire mesh stent protruding from the ampulla for a distance of 1.2 cm.

The pancreas is received with multiple surgical stitches, a long single black stitch designates the deep radial margin, a long single blue stitch designates the portal vein margin, a looped blue stitch designates the superior mesenteric artery margin, and a looped black stitch designates the proximal duodenal margin. The proximal duodenal margin near the area of the looped black stitch is removed and submitted for frozen section. This tissue is resubmitted entirely. The pancreatic neck margin measures 1.6 x 1.5 cm and is inked orange. The vascular groove is inked blue and the remaining radial pancreatic margin is inked black. The pancreas is serially sectioned to reveal a pale tan to white mass that measures 2.7 x 2.2 x 1.6 cm. The mass is 1.4 cm from the SMA margin, 1.2 cm from the portal vein margin, 3 cm from the deep radial margin, and 1 mm from the nearest radial margin. The common bile duct is identified and has a diameter of 0.2 cm. Additionally, the common bile duct is probe patent through the ampulla. A longitudinal cut is made along the common bile duct to reveal the aforementioned wire mesh stent. The stent measures 6.3 cm in

TCD-0-3
Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head 0250
425/10/13

[page 2 of 4]
length and has a diameter of 1.2 cm. A probe is inserted into the main pancreatic duct at pancreatic neck margin. The main pancreatic duct is not probe patent and a longitudinal cut made along the duct determines the lumen is being obstructed by the mass. Of note, representative sections and frozens were taken of the common bile duct margin, pancreatic margin, and duodenal margin and are resubmitted entirely. The remainder of the pancreatic parenchyma is firm, pale tan to yellow with no additional distinct masses or lesions noted.

Microscopic Description:

Diagnosis Details: Pancreas and duodenum, pancreaticoduodenectomy:

- Invasive pancreatic ductal adenocarcinoma, poorly differentiated, of the pancreatic head
- Tumor size: 2.7 cm in greatest dimension
- Tumor focally infiltrates peripancreatic fat
- Surgical margins are negative for malignancy; Tumor is 0.1 cm from nearest radial margin (slide D11)
- Perineural invasion identified
- No angiolymphatic invasion identified
- Eighteen regional lymph nodes, negative for malignancy (0/18)
- Pathologic stage (AJCC 7th edition): pT3 N0

Specimen: Head of pancreas, Duodenum Common bile duct, Gallbladder

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

Tumor Site: Pancreatic head

Tumor size greatest dimension: 2.7cm

Histologic Type: Ductal adenocarcinoma

Histologic Grade (ductal carcinoma only): G3

Microscopic Tumor Extension: Tumor invades peripancreatic soft tissues

[page 3 of 4]
AJCC Stage (7th Edition) (pTNM)

Primary Tumor (pT): pT3

Regional Lymph Nodes (pN): pN0

Number of regional lymph nodes involved: 0

Number of regional lymph nodes examined: 18

Distant Metastasis (pM): Not applicable

Pancreatic neck margin: Negative

Portal vein margin: Negative

Superior mesenteric artery margin: Negative

Deep radial margin: Negative

Duodenom/gastric margin: Negative

Jejunal margin: Negative

Treatment Effect: No prior treatment

Angiolymphatic Invasion: Absent

Perineural Invasion: Present

Additional Pathologic Findings: Chronic pancreatitis

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Pancreatoduodenectomy

Tumor site: Head

Tumor size: 2.7 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Poorly differentiated

Tumor extent: Other - Peripancreatic fat

Lymph nodes: 0/18 positive for metastasis (Regional 0/18)

[page 4 of 4]
Lymphatic invasion: Absent

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file 9ba86c59-8411-40e6-b0ae-813d4f317e10 (TCGA-FB-AAQ0.C40B3100-1BFC-4763-964C-89AECCA0B7F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).